Somatic mutation profile of tumor specimen TARGET-30-PARZMY-06A (aliquot TARGET-30-PARZMY-06A-01D) from TARGET case TARGET-30-PARZMY, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 4.6 years (1,691 days).
Specimen TARGET-30-PARZMY-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 24d59cea-59aa-4477-8c23-f49f71926c87.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PARZMY-10A (Blood Derived Normal), aliquot TARGET-30-PARZMY-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fdb7361e-11db-47c6-af02-fef35d6ee4f4

The open-access MAF lists 30 somatic variants for this specimen: 23 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 21, Silent 7, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.6549G>C p.M2183I (on ENST00000272895 / NM_173076.3; = p.M1865I on NM_015657.3) | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.372); catalogued as COSV55951969, COSV55962762; called by muse, mutect2, varscan2
- BIRC7 | c.306G>C p.E102D | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT tolerated (0.7); PolyPhen benign (0.019); catalogued as COSV53900593; called by muse, mutect2, varscan2
- COL6A6 | c.2540G>T p.R847L | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV62019795; called by muse, mutect2, varscan2
- DNAJC13 | c.4716+2T>C p.X1572_splice | Splice Site (SNP) | VAF 24/73 reads (33%) | catalogued as COSV53447078; called by muse, mutect2, varscan2
- DPP10 | c.617T>A p.I206K | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as COSV59671291; called by muse, mutect2, varscan2
- DYNC1LI1 | c.802C>G p.Q268E | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV56127018; called by muse, mutect2, varscan2
- GAL3ST1 | c.644G>T p.R215L | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.387); catalogued as COSV58891846, COSV58892092; called by muse, mutect2, varscan2
- HTR3D | c.799G>T p.V267F (on ENST00000382489 / NM_001163646.2; = p.V94F on NM_182537.3) | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV61913509; called by muse, mutect2, varscan2
- KALRN | c.2388G>T p.M796I | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.899); catalogued as COSV53755878; called by muse, mutect2, varscan2
- KRT31 | c.1001G>T p.R334L | Missense Mutation (SNP) | VAF 69/268 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs181766476, COSV52433853; called by muse, mutect2, varscan2
- NLRC3 | c.3179C>G p.T1060R | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.026); catalogued as COSV57088598; called by muse, mutect2, varscan2
- OR14A16 | c.755G>T p.G252V | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.38); catalogued as COSV100713812, COSV62926244; called by muse, mutect2, varscan2
- OR1J1 | c.639C>A p.C213* | Nonsense Mutation (SNP) | VAF 46/147 reads (31%) | catalogued as COSV52237534; called by muse, mutect2, varscan2
- OR6Q1 | c.786G>A p.M262I | Missense Mutation (SNP) | VAF 84/259 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.326); catalogued as COSV56932496; called by muse, mutect2, varscan2
- PARD6B | c.1041C>A p.S347R | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.085); catalogued as COSV65404177; called by muse, mutect2, varscan2
- POU1F1 | c.232C>A p.L78I | Missense Mutation (SNP) | VAF 49/138 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.952); catalogued as COSV60155235; called by muse, mutect2, varscan2
- RIOK2 | c.995C>A p.S332Y | Missense Mutation (SNP) | VAF 63/218 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as COSV51611351; called by muse, mutect2, varscan2
- SIGLEC10 | c.625C>A p.H209N | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV100219456, COSV59479706; called by muse, mutect2, varscan2
- SLC6A17 | c.972G>T p.K324N | Missense Mutation (SNP) | VAF 54/123 reads (44%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.959); catalogued as rs776544892, COSV58991771; called by muse, mutect2, varscan2
- SLC9A3R2 | c.448C>G p.R150G | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757611488, COSV54592482, COSV99526342; called by muse, mutect2, varscan2
- SLC9A5 | c.1607C>T p.A536V | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV55360818; called by muse, mutect2, varscan2
- TCN1 | c.211C>A p.L71M | Missense Mutation (SNP) | VAF 95/220 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.897); catalogued as COSV57252481; called by muse, mutect2, varscan2
- TRAF7 | c.964C>A p.L322I | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.352); catalogued as COSV58213133; called by muse, mutect2, varscan2
- ANKRD20A4P | c.1239C>A p.G413= | Silent (SNP) | VAF 26/204 reads (13%) | catalogued as COSV62004042; called by muse, mutect2, varscan2
- CDYL2 | c.462C>T p.N154= | Silent (SNP) | VAF 57/154 reads (37%) | catalogued as rs140729164; called by muse, mutect2, varscan2
- KAT14 | c.678A>T p.I226= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as COSV66607053; called by muse, mutect2, varscan2
- PHKB | c.2229G>T p.L743= | Silent (SNP) | VAF 51/160 reads (32%) | catalogued as COSV54516561; called by muse, mutect2, varscan2
- TECTB | c.927C>A p.L309= | Silent (SNP) | VAF 69/185 reads (37%) | catalogued as COSV65594905, COSV65594999; called by muse, mutect2, varscan2
- ZNF460 | c.1068G>T p.R356= | Silent (SNP) | VAF 42/118 reads (36%) | catalogued as COSV64415391; called by muse, mutect2, varscan2
- ZNF831 | c.4314C>A p.G1438= | Silent (SNP) | VAF 44/128 reads (34%) | catalogued as rs1405379879, COSV64038228; called by muse, mutect2, varscan2
